Surgical pathology report (de-identified scan), TCGA case TCGA-WK-A8XQ, project TCGA-SARC (Sarcoma), tissue source site Brigham and Women's Hospital, specimen TCGA-WK-A8XQ-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Report Status: Final

Type: Surgical Pathology

Specimen Type: Omentum

Procedure Date:

Ordering Provider:

Resident:

Pathologist:

PATHOLOGIC DIAGNOSIS:

A. OMENTUM:

HIGH GRADE SPINDLE CELL NEOPLASM SUGGESTIVE OF
DEDIFFERENTIATED LIPOSARCOMA (17.5 CM) involving adipose tissue
(See Note).

Mitoses number 3 per 10 HPF.

50% necrosis is present.

30% hemorrhage is present.

ICD-O-3

Liposarcoma, dedifferentiated

8858/3

Antropositoneum C48.0

5/5/14

B. MESENTERY SARCOMA:

HIGH GRADE SPINDLE CELL NEOPLASM SUGGESTIVE OF
DEDIFFERENTIATED LIPOSARCOMA (36.5 CM)

Mitoses number 3 per 10 HPF.

50% necrosis is present.

30% hemorrhage is present.

Immunohistochemistry performed at demonstrates the following
staining profile in lesional cells:

Positive - CD99, MDM-2 (focal), CDK4 (focal, weak), S100 (rare cells)
HMB45, Pan-K, CD34, Desmin.

The immunohistochemical profile supports the above diagnosis.

NOTE: MDM2 and CDK4 immunohistochemical stains are weak, focal; a more
diffuse, multifocal appearance is usually seen in dedifferentiated
liposarcoma.

CLINICAL DATA:

History: None given.

Operation: Radical resection intra-abdominal mass, right ureteral stent
placement.

Operative Findings: None given.

Clinical Diagnosis: Intra-abdominal sarcoma.

TISSUE SUBMITTED:

A/1. Omentum.

B/2. Mesentery sarcoma.

GROSS DESCRIPTION:

The specimen is received fresh, in ten parts, each labeled with the patient's
name and unit number.

Part A, "1.Omentum", consists of one fragment of tan/red fibroadipose tissue
(17.5x 15x 2cm). The specimen contains scattered areas of thickening which,
upon sectioning, reveal firm, white/tan, focally hemorrhagic (20%) caked
tissue. Representative sections are submitted for microscopic analysis.

Micro A1-A2: Representative sections of omentum with nodular tissue, two frags,

[page 2 of 2]
Pathology Report

Part B, "2.Mesentery Sarcoma (Tissue Bank)", consists of multiple fragments of tan/yellow, fatty, multifocally hemorrhagic, necrotic soft tissue (3130gm; 36.5x32.5x4.0 cm) with 20% gelatinous clotted blood. Representative sections are submitted to the tissue bank, laboratory, and to cytogenetics.

Micro B1-B15: Representative sections of tumor, randomly sampled, 1-2 frags,

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by

Electronically signed on

Printed:

Source: NCI Genomic Data Commons file 8ef304db-5c34-4816-ae97-b346549b83c0 (TCGA-WK-A8XQ.A82D6748-3D33-462C-AF55-6764AE44D90E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).